TCGA case TCGA-ZF-A9R9 — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Sheffield. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ebad8bc9-f196-4f53-bfea-de38488eb4e1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United Kingdom; Age at index: 58 years; Vital status: Dead; Days to death: 864 days (2.4 years).

Diagnoses (4)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 58.8 years (21,491 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC pathologic T: T3b; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Pathology details: Consistent pathology review: Yes; Extracapsular extension present: No; Lymph nodes positive: 1; Lymph nodes tested: 1; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Penis, NOS. Age at diagnosis: 60.6 years (22,120 days); Days to diagnosis: 629 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.
3. Recurrence of diagnosis 1 (Transitional cell carcinoma), site: Pelvis, NOS. Age at diagnosis: 61.1 years (22,310 days); Days to diagnosis: 819 days (2.2 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
4. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Liver. Age at diagnosis: 61.2 years (22,343 days); Days to diagnosis: 852 days (2.3 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (5 entries)
- Day 629 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Penis, NOS; Days to progression: 629 days (1.7 years).
- Day 819 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pelvis, NOS; Days to recurrence: 819 days (2.2 years).
- Day 852 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 852 days (2.3 years).
- Days to follow up: 864 days (2.4 years); Disease response: With Tumor.
- ECOG performance status: 0.

Exposures
- Occupation duration years: 30; Occupation type: Government Regulatory Associate Professionals.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 3; Tobacco smoking quit year: 1973; Age at onset: 16.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ZF-A9R9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-ZF-A9R9-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-ZF-A9R9-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ZF-A9R9-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: retired; Occupation primary: property inspector; Occupation primary chemical exposure: nil; Occupation primary industry: private property letting; Tobacco smoking history indicator: 3; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: Yes; Incidental prostate cancer indicator: No; Treatment outcome first course: Complete Remission/Response.
- Metastatic site list: Metastasis site: Lymph node only.
- History non muscle invasive blca: Noninvasive bladder history: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 864 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 864 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 629 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ZF-A9R9-01A-11D-A38F-01): tumor purity 0.82, ploidy 3.76, whole-genome doublings 1.
